Gene-level copy-number profile of tumor specimen HTMCP-03-06-02149-01A from CGCI case HTMCP-03-06-02149, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3.
Specimen HTMCP-03-06-02149-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d7bc64f6-00cf-4341-ab7f-be6de57a30db.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02149-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,257 have no estimate.
https://portal.gdc.cancer.gov/files/6d21bd3c-bde6-40e1-b2e2-ec2fa0e7bbe4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1; copy number 2: 1,688; copy number 3: 15,872; copy number 4: 22,313; copy number 5: 7,703; copy number 6: 6,539; copy number 7: 776; copy number 8: 3,075; copy number 9: 208; copy number 10: 103; copy number 11: 72; copy number 12: 14; copy number 34: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:32,517,353–32,530,287, 1 gene: HLA-DRB5.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 398 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:246,682,108–246,691,821, 2 genes, copy number 9: AL591848.2, AL591848.1.
- chr3:106,449,775–107,240,671, 1 gene, copy number 9 (within-gene range 8–9): LINC00882.
- chr3:106,684,388–108,589,644, 36 genes, copy number 9: AC080097.1, Y_RNA, FCF1P3, MTND4P16, MTND4LP3, MTND3P6, MTCO3P35, MTATP6P22, MTND5P16, MTND6P6, MTCO1P35, MTND1P16, MTND2P14, RNU6-1308P, AC117435.1, AC074043.1, DUBR, AC063944.1, CSP2, AC063944.2, CCDC54, LINC01990, BBX, LINC00636, LINC00635, AC012020.1, CD47, LINC01215, IFT57, HHLA2, HNRNPA1P17, MYH15, AC069499.1, CIP2A, SNORA70, AC069499.2.
- chr3:161,324,913–161,821,908, 8 genes, copy number 9: EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1, AC131211.1.
- chr3:188,153,284–188,890,671, 1 gene, copy number 9 (within-gene range 8–9): LPP.
- chr3:188,562,238–190,892,429, 25 genes, copy number 9: LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC.
- chr3:193,398,967–196,536,702, 111 genes, copy number 9 (broad region; genes not listed).
- chr7:38,239,580–38,249,572, 1 gene, copy number 12: TRGC2.
- chr7:38,256,337–38,330,935, 13 genes, copy number 12: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8.
- chr8:127,686,343–127,742,951, 2 genes, copy number 9–34: CASC11, MYC.
- chr9:2,228,961–2,643,359, 3 genes, copy number 10 (within-gene range 8–10): RN7SL592P, VLDLR-AS1, AL353614.1.
- chr9:11,275,314–16,410,990, 56 genes, copy number 9–11 (within-gene range 7–11): AL451129.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B, RPL7P33, SNAPC3, RNU6-319P, PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P, CCDC171, HMGN2P16, RNU6-14P, C9orf92.
- chr14:22,265,749–22,520,031, 56 genes, copy number 11: TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44, TRAJ43, TRAJ42, TRAJ41, TRAJ40, TRAJ39, TRAJ38, TRAJ37, TRAJ36, TRAJ35, TRAJ34, TRAJ33, TRAJ32, TRAJ31, TRAJ30, TRAJ29, TRAJ28, TRAJ27, TRAJ26, TRAJ25, TRAJ24.
- chr14:22,547,506–22,552,156, 1 gene, copy number 11: TRAC.
- chr20:61,953,469–63,537,376, 82 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
